CCDI case PBCFPF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/b20b2597-3c77-4963-87a2-eafd46a03643

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 10.8 years (3,932 days).

Biospecimens (3 samples)
- Sample 0DRE0G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DRE0O, 0DRE0Y (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
